Gene-level copy-number profile of tumor specimen HTMCP-01-06-00443-01A from CGCI case HTMCP-01-06-00443, project CGCI-HTMCP-DLBCL (HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 43.7 years (15,978 days).
Specimen HTMCP-01-06-00443-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 67cdc450-8ff6-4453-9a1a-c0a3ad372ed1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-01-06-00443-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/56d35c1b-e5c2-46f2-997c-60bdc6cf35e7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 11,048; copy number 2: 39,806; copy number 3: 7,349; copy number 4: 175.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:162,022,733–163,119,965, 6 genes (within-gene range 0–1): AC023136.1, MTHFD2P4, TOMM22P4, AC021134.1, AC084752.1, AC022272.1.
- chr14:105,639,559–105,673,314, 5 genes (within-gene range 0–2): IGHG2, MIR8071-2, COPDA1, IGHGP, ELK2AP.
- chr14:105,721,794–105,722,527, 1 gene (within-gene range 0–2): IGHEP1.
- chr19:6,531,026–6,573,057, 4 genes: TNFSF9, AC010503.3, CLIC4P2, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 9,014. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
